Surgical pathology report (de-identified scan), TCGA case TCGA-18-3406, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Princess Margaret Hospital (Canada), specimen TCGA-18-3406-01A (Primary Tumor).

[page 1 of 3]
Copath #:
Collected:
Resulted:

Surgical Pathology Consultation Report

SPECIMEN(S) RECEIVED

1. Soft-Tissue: tissue near aorta / QS
2. LUNG: BIOPSY LEFT UPPER LOBE / QS
3. Lymph node: A-P WINDOW NODE
4. LUNG: NODULE ON PLEURA NEAR AORTA / QS
5. LUNG: COMPLETION LT PNEUMONECTOMY

DIAGNOSIS

1. Tissue near aorta - Fibrous connective tissue: No neoplasia
2. Biopsy, left upper lobe bronchus - Fragments of squamous cell carcinoma with no associated stroma
therefore
precluding assessment of invasion
3. AP window lymph node - Negative for malignancy
4. Nodule on pleura near aorta - Lymph node within connective tissue - No neoplasia
5. Completion left pneumonectomy
- a) Invasive well-differentiated squamous cell carcinoma, 2.0 cm maximum dimension, peripheral with no invasion into pleura
- b) Bronchial margin of resection - Negative for malignancy
- c) Two interlobar and one segmental lymph node - Negative for malignancy.

COMMENT

Examination of this material indicates apparent complete resection of a T1N0 squamous cell carcinoma. This appears to be metachronous to a tumor at the patient had undergone a lower lobectomy for in .

[page 2 of 3]
[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

Copath #:

Collected: [REDACTED]

Resulted: [REDACTED]

[REDACTED]

CLINICAL HISTORY

Cancer. lung

GROSS DESCRIPTION

1. The specimen container labeled with the patient' s name and as "tissue near aorta q.s", contains a single piece of tissue measuring 0.8 x 0.3 x 1 cm received fresh. This was examined at intraoperative consultation frozen section performed on the entire specimen.

1A frozen section embedded in toto resubmitted

2. The specimen container labeled with the patient' s name and as "biopsy left upper lobe q.s", contains multiple tiny tan pieces of tissue measuring collectively 0.2 x 0.2 x 0.1 cm received fresh. This was examined at intraoperative consultation by frozen section performed on the entire specimen.

2A frozen section embedded in toto resubmitted

3. The specimen container labeled with the patient' s name and as "AP window node", contains five pieces of yellowish black tissue measuring from 0.3 x 0.2 x 0.1 cm up to 2.0 x 0.8 x 0.4 cm. received in 10% buffered formalin.

3A submitted in toto.

4. The specimen container labeled with the patient' s name and as "nodule on pleura near aorta q.s.", contains a piece of pink-tan tissue measuring 1.5 x 1.5 x 0.2 cm received fresh. This was examined at intraoperative consultation by frozen section performed on the entire specimen.

4A embedded in toto resubmitted

5. The specimen container labeled with the patient' s name and as "completion left pneumonectomy", contains a greyish-tan predominantly left upper lobe of the lung measuring 21.0 x 15.5 x 11.0 cm received in 10% buffered formalin. There are pleural adhesions noted with organized fibrinous exudate on most portion of the lung tissue and there is a torn pleura associated by the lower aspect of the specimen. On sectioning there is peripheral tumor associated with fibrous adhesion _____

[page 3 of 3]
[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

Copath #:
Collected: [REDACTED]
Resulted: [REDACTED]

located posterior aspect at the level of the main stem bronchus. The tumor is well circumscribed yellowish-tan firm measuring 2.0 cm in maximum dimension. On further sectioning the remainder of the lung tissue appears to be grossly unremarkable. One interlobar lobe is bisected and multiple segmental nodes measuring from 0.8 cm in maximum dimension. Representative sections are submitted as follows:

5A bronchial resection margin

5B one interlobar node

5C four segmental nodes

5D -5F representative section of the tumor

5G-6I representative section of apparently normal lung parenchyma

piece of tumoral tissue and piece of alveolar tissue and pieces of bronchial mucosa tissue are taken for tissue frozen.
? submitted in toto.

[REDACTED]

QUICK SECTION

1A "Fibrovascular negative for carcinoma"

4A "Fibrous tissue and focal chronic inflammation"

[REDACTED]

Source: NCI Genomic Data Commons file 18fc06e4-776c-4679-a754-eecead797f56 (TCGA-18-3406.A0EEF850-7543-4F82-8E46-3D81E203412D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).